Somatic mutation profile of tumor specimen MMRF_1830_1_BM_CD138pos (aliquot MMRF_1830_1_BM_CD138pos_T1_KBS5U_K11307) from MMRF case MMRF_1830, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.5 years (25,372 days).
Specimen MMRF_1830_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9adf2895-1656-46b4-acc7-d96af00d9352.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1830_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1830_1_PB_CD3pos_C2_KBS5U_K11308; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa9e2f12-7f39-4773-b333-7e3fb7bcc927

The open-access MAF lists 96 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 23, Silent 13, Intron 12, 5'UTR 4, 5'Flank 3, 3'Flank 2, Nonsense Mutation 2, Splice Region 2, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 75/187 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD13B | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs562706819, COSV101198970; called by muse, mutect2, varscan2
- ANO1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs367716754; called by muse, mutect2, varscan2
- APBA2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs371759617; called by muse, mutect2, varscan2
- BBS4 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs769766779; called by muse, mutect2, varscan2
- CA2 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769398095; called by muse, mutect2, varscan2
- CLIP2 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs538503335; called by muse, mutect2, varscan2
- DZIP1 | c.2111C>T p.P704L (on ENST00000347108; = p.P685L on NM_014934.5) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs144822400; called by muse, mutect2, varscan2
- IGHV2-70 | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs1555607329; called by muse, varscan2
- IGLL5 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as rs763474712, COSV73248991, COSV73251236, COSV73251304; called by muse, mutect2, varscan2
- KCNT1 | c.1324G>A p.E442K (on ENST00000488444; = p.E461K on NM_020822.3) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as rs141311481; called by muse, mutect2, varscan2
- KDM5C | c.2828G>A p.R943Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781785252, COSV64763243; called by muse, mutect2, varscan2
- MSTN | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.239); catalogued as rs772177439, COSV53620301; called by muse, mutect2, varscan2
- MUC12 | c.14792C>G p.S4931* (on ENST00000379442; = p.S4788* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 13/118 reads (11%) | catalogued as rs1369160065; called by muse, mutect2, varscan2
- OR2W1 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | catalogued as rs371360591, COSV65852093; called by muse, mutect2, varscan2
- TCL1A | c.120+1G>C p.X40_splice | Splice Site (SNP) | VAF 49/115 reads (43%) | catalogued as rs560011205, COSV68085095, COSV68085701; called by muse, mutect2, varscan2
- TCL1A | c.120G>A p.E40= | Splice Region (SNP) | VAF 50/116 reads (43%) | catalogued as rs767730962, COSV101268493; called by muse, mutect2, varscan2
- VPS13A | c.7263G>C p.K2421N | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.562); catalogued as rs1215403260; called by muse, mutect2, varscan2
- YBX2 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1404773914; called by muse, mutect2, varscan2
- ZNF384 | c.1437_1460del p.Q489_A496del (on ENST00000361959; = p.Q428_A435del on NM_133476.5) | In Frame Del (DEL) | VAF 24/63 reads (38%) | catalogued as rs755405093; called by muse*, mutect2
- AL592490.1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARRDC3 | c.908T>G p.L303R | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- BAHCC1 | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DAPL1 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IGHD3-16 | c.35A>C p.Y12S | Missense Mutation (SNP) | VAF 25/25 reads (100%) | called by muse, varscan2
- KLHL41 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LY6K | c.217+3G>A | Splice Region (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2, varscan2
- MED15 | c.501G>C p.Q167H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MROH9 | c.2194A>G p.N732D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- NAA25 | c.560A>T p.E187V | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- OR1S2 | c.626A>T p.E209V | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- PARD3 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- RBM12B | c.216dup p.L73Sfs*2 | Frame Shift Ins (INS) | VAF 70/332 reads (21%) | called by mutect2, varscan2
- RCL1 | c.460-1G>C p.X154_splice | Splice Site (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- RNF40 | c.773A>C p.Y258S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SLC25A3 | c.901C>G p.L301V (on ENST00000228318 / NM_005888.3; = p.L300V on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SYDE2 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- TET2 | c.3187_3197del p.T1063* | Frame Shift Del (DEL) | VAF 52/212 reads (25%) | called by mutect2, pindel, varscan2
- CA12 | c.543G>A p.P181= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as rs371863633; called by muse, mutect2, varscan2
- CDH13 | c.2094C>T p.S698= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- CIITA | c.1671G>C p.L557= | Silent (SNP) | VAF 5/113 reads (4%) | called by muse, mutect2
- COL19A1 | c.1086G>A p.L362= | Silent (SNP) | VAF 9/178 reads (5%) | catalogued as COSV100505934, COSV59564451; called by muse, mutect2
- JPH4 | c.300C>T p.S100= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs570284347; called by muse, mutect2, varscan2
- LILRB5 | c.1311C>G p.G437= (on ENST00000449561 / NM_001081442.3; = p.G436= on NM_006840.5) | Silent (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- MAFB | c.765C>T p.C255= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs541401457, COSV100965042; called by muse, mutect2, varscan2
- MYO3A | c.2383A>C p.R795= | Silent (SNP) | VAF 92/167 reads (55%) | called by muse, mutect2, varscan2
- NFASC | c.2046C>T p.P682= (on ENST00000339876 / NM_001378329.1; = p.P678= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/201 reads (31%) | catalogued as rs768250957, COSV58361844, COSV58379379; called by muse, mutect2, varscan2
- NPTX1 | c.1242C>T p.I414= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs146777310, COSV100151221, COSV60776985; called by muse, mutect2, varscan2
- SYCP2 | c.2313G>A p.E771= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as rs1315585816, COSV62767302; called by muse, mutect2
- TBC1D1 | c.129T>C p.V43= | Silent (SNP) | VAF 59/98 reads (60%) | called by muse, mutect2, varscan2
- UBR5 | c.8328C>G p.L2776= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as COSV55284463; called by muse, mutect2
- ACOT7 | c.-57G>A | 5'UTR (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- ATP6V1F | c.159-392G>A | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- BMP5 | c.*95A>T | 3'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- CARD6 | chr5:40841363 G>C | 5'Flank (SNP) | VAF 54/107 reads (50%) | called by muse, mutect2, varscan2
- CCDC148 | c.-52C>T | 5'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- CDH19 | c.*3386C>T | 3'UTR (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- CHCHD3 | c.170-10627_170-10624dup | Intron (INS) | VAF 56/128 reads (44%) | called by mutect2, varscan2
- DIP2C | c.*2360G>A | 3'UTR (SNP) | VAF 5/48 reads (10%) | catalogued as rs1029753836; called by muse, mutect2, varscan2
- DPP10 | c.*1707C>T | 3'UTR (SNP) | VAF 20/35 reads (57%) | catalogued as rs1483242728; called by muse, mutect2, varscan2
- EVX1 | chr7:27239917 T>C | 5'Flank (SNP) | VAF 38/66 reads (58%) | called by muse, mutect2, varscan2
- GASK1B | c.910+1734T>G | Intron (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- GGACT | c.*557C>T | 3'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as rs1000682720; called by muse, mutect2
- GNA14 | c.-44G>A | 5'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- HMCN1 | c.*929C>T | 3'UTR (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- HOXB5 | c.*87C>T | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- LINC00523 | n.1387G>A | RNA (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- LSS | c.*295C>A | 3'UTR (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- LTB | c.163-179T>A | Intron (SNP) | VAF 57/156 reads (37%) | catalogued as rs534717676; called by muse, mutect2, varscan2
- MEF2D | c.*777_*779del | 3'UTR (DEL) | VAF 44/185 reads (24%) | called by pindel, varscan2
- MIR9-1 | chr1:156416708 G>A | 3'Flank (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2
- MPPED2 | c.*4178G>A | 3'UTR (SNP) | VAF 12/23 reads (52%) | catalogued as rs1427941460; called by muse, mutect2, varscan2
- MYRF | c.2014-115T>C | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- NFKB1 | c.569-51T>C | Intron (SNP) | VAF 55/186 reads (30%) | called by muse, mutect2, varscan2
- NRBP2 | c.445-36C>A | Intron (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- NRP1 | c.1864+225G>A | Intron (SNP) | VAF 25/59 reads (42%) | catalogued as rs548084409; called by muse, mutect2, varscan2
- PCDH17 | c.*2864C>T | 3'UTR (SNP) | VAF 17/17 reads (100%) | catalogued as COSV64977416; called by muse, mutect2, varscan2
- PDE4D | c.*3626T>C | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- PKNOX1 | c.*3495T>C | 3'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- PLEKHG3 | chr14:64749212 G>A | 3'Flank (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- PPP1R16B | c.*3942_*3972del | 3'UTR (DEL) | VAF 23/53 reads (43%) | called by mutect2, pindel
- RAB27B | c.*2172A>T | 3'UTR (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- RASGEF1B | c.438+3643_438+3644insC | Intron (INS) | VAF 8/94 reads (9%) | called by pindel, varscan2*
- RHOT1 | chr17:32142156 del C | 5'Flank (DEL) | VAF 26/52 reads (50%) | called by mutect2, pindel, varscan2
- SERTAD4 | c.*1953T>G | 3'UTR (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.*2219G>T | 3'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- TFAP2A | c.-78-33T>C | Intron (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100116603; called by muse, mutect2
- TMEM145 | c.1402-305A>G | Intron (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- TMEM236 | c.*850C>T | 3'UTR (SNP) | VAF 8/10 reads (80%) | catalogued as rs1298084258; called by muse, mutect2, varscan2
- TMTC3 | c.*1862_*1863del | 3'UTR (DEL) | VAF 9/66 reads (14%) | called by pindel, varscan2
- TNIK | c.*236C>A | 3'UTR (SNP) | VAF 46/98 reads (47%) | catalogued as rs559650002; called by muse, mutect2, varscan2
- TRAF1 | c.*1272G>A | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- TRMT10A | c.*793_*797delinsTCCATAT | 3'UTR (INS) | VAF 8/62 reads (13%) | called by pindel, varscan2*
- TSPAN19 | c.595-17T>A | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- UBE3D | c.*218C>T | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- UBOX5 | c.-11C>T | 5'UTR (SNP) | VAF 22/166 reads (13%) | catalogued as rs751024948; called by muse, mutect2, varscan2
